CCDI case PBCCRL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a612d1e2-7d4f-498a-b7bc-1ed9b6897f51

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Hemangioma, NOS: ICD-O-3 morphology code: 9120/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.3 years (6,336 days).

Biospecimens (4 samples)
- Sample 0DP6HG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DP6HZ, 0DPFMH (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DP6I7: Tissue type: Tumor; Specimen type: Solid Tissue.
